Surgical pathology report (de-identified scan), TCGA case TCGA-05-4410, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4410-01A (Primary Tumor).

Main diagnosis/diagnoses:

Pulmonary wedge resection material with peripheral manifestation of a focally mucin-forming adenocarcinoma (sample 1.) showing a predominantly tubular or acinar structure, in parts a bronchioloalveolar growth pattern and a small solid and papillary component.

Comment/supplementary remark:

According to the conventional histology, the findings are consistent with a peripheral mixed bronchopulmonary adenocarcinoma (C 34.1, M 8255/3), the TNM classification of which on the basis of these samples is pT2 pN0 pMX L1 V1 RX, corresponding to stage IB.

(Immunohistological analysis as to the tumor's point origin will follow.) The tumor shows foci of infiltration in the visceral pleura and extends to the basal resection margin, which gives rise to RX classification from the patho-anatomical viewpoint.

The immune profile (positive for cytokeratin 7 and TTF-1, negative for cytokeratin 20 and CDX-2) confirms the bronchopulmonary origin of the tumor.

Source: NCI Genomic Data Commons file 65a032c9-3a59-4846-848c-15186884d94c (TCGA-05-4410.13C40632-79E2-485C-9EF2-DA6D075B054C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).